Somatic mutation profile of tumor specimen HCM-SANG-0310-C15-01A (aliquot HCM-SANG-0310-C15-01A-01D-A78U-36) from HCMI case HCM-SANG-0310-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0310-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f2713f5-a8a0-4e25-a48e-656fd4617c82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0310-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0310-C15-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95ff7e59-2349-4264-812f-439185169753

The open-access MAF lists 162 somatic variants for this specimen: 112 protein-altering or splice-affecting, 31 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 31, Splice Site 8, 3'UTR 7, Intron 6, Nonsense Mutation 5, Frame Shift Del 5, RNA 3, In Frame Del 2, Frame Shift Ins 2, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 113/167 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ARID1A | c.2899A>T p.M967L | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV61390820; called by muse, mutect2, varscan2
- ARMCX3 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 54/67 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868995472, COSV100362190; called by muse, mutect2, varscan2
- CCDC88A | c.5239C>T p.R1747W (on ENST00000436346 / NM_001365480.1; = p.R1719W on NM_018084.5) | Missense Mutation (SNP) | VAF 133/340 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as rs371735739; called by muse, mutect2, varscan2
- CNTNAP3B | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 156/643 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs2935316; called by muse, mutect2, varscan2
- COL8A1 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as rs777725434, COSV53729747; called by mutect2, varscan2
- CPNE1 | c.847C>G p.Q283E (on ENST00000352393; = p.Q288E on NM_003915.5) | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV100467971; called by muse, mutect2, varscan2
- CR1 | c.923G>A p.R308H (on ENST00000367051; = p.R758H on NM_000651.6) | Missense Mutation (SNP) | VAF 78/497 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs989786536; called by muse, mutect2, varscan2
- EBF1 | c.1128A>C p.E376D | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV58166123; called by muse, mutect2, varscan2
- EIF2AK1 | c.1463del p.T488Sfs*34 | Frame Shift Del (DEL) | VAF 90/308 reads (29%) | catalogued as COSV52235862, COSV52242724; called by mutect2, pindel, varscan2
- EXD3 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as rs577049845, COSV59808510, COSV59808802; called by muse, mutect2, varscan2
- FAT4 | c.7523C>T p.S2508L | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs267600010, COSV58702558; called by muse, mutect2, varscan2
- GIMAP5 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs533934192; called by muse, mutect2, varscan2
- HMG20A | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 50/156 reads (32%) | catalogued as rs1263163087; called by mutect2, varscan2
- HTR3C | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs369321709, COSV59177853; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 83/365 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.967); catalogued as rs766731472; called by muse, mutect2, varscan2
- KCNA5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 185/589 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52904231; called by muse, mutect2, varscan2
- KCNB2 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 52/536 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs771065845, COSV73049176; called by muse, mutect2, varscan2
- KCND2 | c.1301G>C p.R434P | Missense Mutation (SNP) | VAF 118/577 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV58582332; called by muse, mutect2, varscan2
- KDM7A | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.042); catalogued as rs1465519693; called by muse, mutect2
- MUC4 | c.6973A>G p.S2325G | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.159); catalogued as rs3103957; called by muse, varscan2
- MUC5AC | c.13912G>A p.D4638N | Missense Mutation (SNP) | VAF 66/405 reads (16%) | SIFT deleterious (0); catalogued as rs569068445; called by muse, mutect2, varscan2
- NRDC | c.1822dup p.R608Kfs*4 | Frame Shift Ins (INS) | VAF 12/52 reads (23%) | catalogued as rs767087523; called by mutect2, pindel, varscan2
- NTSR1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 72/659 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372116403; called by muse, mutect2, varscan2
- NUB1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 91/264 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs370093318; called by muse, mutect2, varscan2
- OR2T1 | c.881A>C p.K294T | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV63541165; called by muse, mutect2, varscan2
- OR4C16 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199938003, COSV58942583; called by muse, mutect2, varscan2
- OR6N2 | c.344T>G p.L115R | Missense Mutation (SNP) | VAF 116/280 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100210364, COSV59410636; called by muse, mutect2, varscan2
- P4HA3 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 216/454 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs756005378, COSV100525927; called by muse, mutect2, varscan2
- POLL | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 218/323 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1447671878; called by muse, mutect2, varscan2
- PREX2 | c.3482G>A p.C1161Y | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs917716947, COSV55788356; called by muse, mutect2, varscan2
- RABEPK | c.761_762del p.H254Rfs*30 | Frame Shift Del (DEL) | VAF 96/277 reads (35%) | catalogued as rs777035658; called by mutect2, pindel, varscan2
- RHBG | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 165/470 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1409098664, COSV54801855; called by muse, mutect2, varscan2
- RPL10L | c.235A>C p.S79R | Missense Mutation (SNP) | VAF 121/479 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as COSV53560159; called by muse, mutect2, varscan2
- SCPEP1 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 130/437 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.721); catalogued as rs764552208; called by muse, mutect2, varscan2
- SPTA1 | c.5192A>T p.E1731V | Missense Mutation (SNP) | VAF 130/787 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV63754427; called by muse, mutect2, varscan2
- STAB1 | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs150259424; called by muse, mutect2, varscan2
- TAAR8 | c.635T>C p.M212T | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1295027482; called by muse, mutect2
- TRIO | c.5668-2A>T p.X1890_splice | Splice Site (SNP) | VAF 184/448 reads (41%) | catalogued as COSV60079290; called by muse, mutect2, varscan2
- ZMYM6 | c.1594C>G p.R532G | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.306); catalogued as COSV100593196; called by muse, mutect2, varscan2
- ZNF366 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 122/461 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.549); catalogued as rs151140704; called by muse, mutect2, varscan2
- ZNF776 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV57815356; called by muse, mutect2, varscan2
- ZNF85 | c.1418A>C p.K473T | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV100060236; called by muse, mutect2, varscan2
- ACSS2 | c.375-1G>A p.X125_splice | Splice Site (SNP) | VAF 76/326 reads (23%) | called by muse, mutect2, varscan2
- ADCY1 | c.1373A>G p.Y458C | Missense Mutation (SNP) | VAF 99/540 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRV1 | c.17144T>A p.V5715E | Missense Mutation (SNP) | VAF 200/291 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- AHRR | c.352-1G>A p.X118_splice | Splice Site (SNP) | VAF 31/246 reads (13%) | called by muse, mutect2, varscan2
- ALDOA | c.397C>G p.L133V (on ENST00000642816 / NM_001243177.4; = p.L79V on NM_184041.5) | Missense Mutation (SNP) | VAF 199/1117 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- APOB | c.3502C>A p.H1168N | Missense Mutation (SNP) | VAF 41/597 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2
- C1orf167 | c.2120C>A p.A707D | Missense Mutation (SNP) | VAF 94/249 reads (38%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- CACNA1A | c.5239T>G p.F1747V | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- CACNA1E | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASTOR1 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 69/325 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CC2D1B | c.1834C>A p.L612I | Missense Mutation (SNP) | VAF 121/373 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CCDC146 | c.1920-2A>G p.X640_splice | Splice Site (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- CCDC175 | c.2044G>T p.E682* | Nonsense Mutation (SNP) | VAF 46/192 reads (24%) | called by muse, mutect2, varscan2
- CHFR | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNA3 | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 81/125 reads (65%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- DDI1 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 146/368 reads (40%) | called by muse, mutect2, varscan2
- DNAH12 | c.6216_6219+2del p.X2072_splice (on ENST00000351747; = p.X2091_splice on NM_001366028.2) | Splice Site (DEL) | VAF 21/42 reads (50%) | called by mutect2, pindel, varscan2
- DNHD1 | c.8729C>T p.A2910V | Missense Mutation (SNP) | VAF 141/489 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EP300 | c.3164G>A p.R1055Q | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ERV3-1 | c.316C>A p.Q106K | Missense Mutation (SNP) | VAF 49/412 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVI5L | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 50/818 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- FRZB | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GIGYF1 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GLCE | c.213_215del p.Q72del | In Frame Del (DEL) | VAF 20/130 reads (15%) | called by pindel, varscan2
- GOLGA6L10 | c.639G>C p.E213D | Missense Mutation (SNP) | VAF 902/3400 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.22); called by muse, varscan2
- GPC3 | c.303G>C p.K101N | Missense Mutation (SNP) | VAF 193/251 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- HNRNPUL1 | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 124/241 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- HOXA4 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HP1BP3 | c.1332_1334del p.E444del | In Frame Del (DEL) | VAF 47/141 reads (33%) | called by pindel, varscan2
- KIZ | c.936G>C p.E312D | Missense Mutation (SNP) | VAF 106/476 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2
- KIZ | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 106/467 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- LIMCH1 | c.168-1G>T p.X56_splice | Splice Site (SNP) | VAF 126/199 reads (63%) | called by muse, mutect2, varscan2
- LIPI | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- LRIG1 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 101/409 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRTM1 | c.719T>A p.V240E | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.2076G>T p.E692D | Missense Mutation (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- MAGEC1 | c.110T>G p.I37S | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- METAP2 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MIEF2 | c.555_585delinsCC p.L186Pfs*36 | Frame Shift Del (DEL) | VAF 40/71 reads (56%) | called by pindel, varscan2*
- MITF | c.1298C>T p.A433V (on ENST00000448226 / NM_006722.3; = p.A333V on NM_000248.4) | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MROH9 | c.1736C>T p.T579I | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MTMR4 | c.1593G>T p.W531C | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAPRT | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 137/539 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- NEIL2 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEIL2 | c.461A>T p.K154M | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- OGT | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 106/157 reads (68%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- OR1A1 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 105/298 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- OR2T3 | c.948A>C p.Q316H | Missense Mutation (SNP) | VAF 89/646 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T34 | c.948A>C p.Q316H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- OSM | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PDHB | c.700+2T>C p.X234_splice | Splice Site (SNP) | VAF 69/249 reads (28%) | called by muse, mutect2, varscan2
- PIP5K1A | c.833T>A p.L278H (on ENST00000368888 / NM_001135638.2; = p.L265H on NM_003557.3) | Missense Mutation (SNP) | VAF 24/896 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0.021); called by muse, mutect2
- PIWIL4 | c.1622A>T p.D541V | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- POF1B | c.1286T>A p.L429* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- PRICKLE4 | c.605A>G p.E202G (on ENST00000359201; = p.E242G on NM_013397.6) | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2
- RARA | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 191/608 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RELN | c.2003-1G>A p.X668_splice | Splice Site (SNP) | VAF 97/442 reads (22%) | called by muse, mutect2, varscan2
- RGS4 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 182/403 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPG7 | c.674A>C p.K225T | Missense Mutation (SNP) | VAF 144/822 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SPRR3 | c.35dup p.P13Tfs*51 | Frame Shift Ins (INS) | VAF 54/372 reads (15%) | called by pindel, varscan2
- SYT1 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- TBC1D8 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBE2E1 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 99/468 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP54 | c.4075_4087del p.R1359Pfs*80 | Frame Shift Del (DEL) | VAF 59/120 reads (49%) | called by mutect2, pindel, varscan2
- VPS13B | c.11311G>C p.D3771H | Missense Mutation (SNP) | VAF 289/777 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H12C | c.2552C>A p.P851H | Missense Mutation (SNP) | VAF 55/417 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ZFHX4 | c.3761T>C p.V1254A | Missense Mutation (SNP) | VAF 76/771 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.048); called by muse, mutect2
- ZNF461 | c.101T>A p.V34E | Missense Mutation (SNP) | VAF 91/390 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF735 | c.437del p.N146Tfs*40 | Frame Shift Del (DEL) | VAF 56/403 reads (14%) | called by mutect2, pindel, varscan2
- ABCC9 | c.1425A>C p.T475= | Silent (SNP) | VAF 89/273 reads (33%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.3183C>T p.D1061= | Silent (SNP) | VAF 184/289 reads (64%) | catalogued as rs1457480819; called by muse, mutect2, varscan2
- AMPH | c.1434A>T p.G478= | Silent (SNP) | VAF 120/667 reads (18%) | called by muse, mutect2, varscan2
- ARNT | c.588T>A p.V196= | Silent (SNP) | VAF 169/1001 reads (17%) | called by muse, mutect2, varscan2
- CD28 | c.639C>T p.R213= | Silent (SNP) | VAF 47/179 reads (26%) | catalogued as rs142698532; called by muse, mutect2, varscan2
- CNTNAP2 | c.3036G>T p.G1012= | Silent (SNP) | VAF 94/448 reads (21%) | catalogued as COSV62167490; called by muse, mutect2, varscan2
- EMILIN2 | c.336C>T p.G112= | Silent (SNP) | VAF 56/143 reads (39%) | called by muse, mutect2, varscan2
- FAT1 | c.9888G>A p.E3296= | Silent (SNP) | VAF 56/203 reads (28%) | catalogued as COSV101499389; called by muse, mutect2, varscan2
- FGF10 | c.18G>C p.L6= | Silent (SNP) | VAF 77/553 reads (14%) | called by muse, mutect2, varscan2
- FMN2 | c.4872A>G p.Q1624= | Silent (SNP) | VAF 38/192 reads (20%) | catalogued as COSV60422561, COSV60449037; called by muse, mutect2, varscan2
- FPR3 | c.747T>C p.S249= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as rs200983333; called by muse, mutect2, varscan2
- GATAD2A | c.714G>A p.A238= | Silent (SNP) | VAF 67/253 reads (26%) | catalogued as rs776225444; called by muse, mutect2, varscan2
- GSX2 | c.444G>A p.A148= | Silent (SNP) | VAF 168/488 reads (34%) | catalogued as COSV100482565; called by muse, mutect2, varscan2
- JPH1 | c.1401G>A p.E467= | Silent (SNP) | VAF 90/384 reads (23%) | called by muse, mutect2, varscan2
- KISS1R | c.813C>T p.L271= | Silent (SNP) | VAF 211/317 reads (67%) | called by muse, mutect2, varscan2
- MRGPRF | c.915G>A p.P305= | Silent (SNP) | VAF 129/556 reads (23%) | catalogued as rs746826672; called by muse, mutect2, varscan2
- NEIL2 | c.372A>G p.A124= | Silent (SNP) | VAF 66/402 reads (16%) | called by muse, varscan2
- NRXN1 | c.3654G>A p.T1218= | Silent (SNP) | VAF 100/402 reads (25%) | catalogued as rs765748728, COSV60509513; called by muse, mutect2, varscan2
- NRXN1 | c.624G>A p.P208= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV68020987; called by muse, mutect2
- NUFIP1 | c.960G>A p.K320= | Silent (SNP) | VAF 76/524 reads (15%) | called by muse, mutect2, varscan2
- OR2B2 | c.429G>A p.Q143= | Silent (SNP) | VAF 49/157 reads (31%) | called by muse, mutect2, varscan2
- OR2L13 | c.93C>T p.I31= | Silent (SNP) | VAF 84/438 reads (19%) | called by muse, mutect2, varscan2
- PARD3B | c.516G>A p.Q172= | Silent (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1887C>T p.G629= | Silent (SNP) | VAF 257/406 reads (63%) | catalogued as rs781815602, COSV56548256; called by muse, mutect2, varscan2
- PGR | c.1816A>C p.R606= | Silent (SNP) | VAF 43/401 reads (11%) | catalogued as rs1297070552, COSV54796446; called by muse, mutect2, varscan2
- SACS | c.7227A>G p.Q2409= | Silent (SNP) | VAF 47/205 reads (23%) | catalogued as rs752932765; called by muse, mutect2, varscan2
- SF3B1 | c.1725C>T p.L575= | Silent (SNP) | VAF 55/221 reads (25%) | catalogued as rs764654037, COSV59219791; called by muse, mutect2, varscan2
- SMCO2 | c.450C>T p.D150= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as rs367878856; called by muse, mutect2, varscan2
- SNAI2 | c.711T>C p.D237= | Silent (SNP) | VAF 175/470 reads (37%) | catalogued as rs1216935277; called by muse, mutect2, varscan2
- SNX18 | c.1248C>T p.A416= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as rs1170752348; called by muse, mutect2
- TRIM64C | c.523A>C p.R175= | Silent (SNP) | VAF 45/271 reads (17%) | catalogued as COSV73267151, COSV73267327; called by muse, mutect2, varscan2
- AACS | c.358+1607C>T | Intron (SNP) | VAF 200/691 reads (29%) | called by muse, mutect2
- CEROX1 | n.2864G>A | RNA (SNP) | VAF 210/1030 reads (20%) | called by muse, varscan2
- CHRNA4 | c.*881G>A | 3'UTR (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2, varscan2
- DCHS2 | n.6679_6682dup | RNA (INS) | VAF 41/170 reads (24%) | called by mutect2, pindel, varscan2
- ERVV-1 | chr19:53010430 C>A | 5'Flank (SNP) | VAF 97/383 reads (25%) | called by muse, mutect2, varscan2
- FBXL8 | chr16:67164450 A>T | 3'Flank (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- FCRL2 | c.*14C>A | 3'UTR (SNP) | VAF 26/181 reads (14%) | catalogued as COSV63833717; called by muse, mutect2, varscan2
- FMR1 | c.*129G>A | 3'UTR (SNP) | VAF 59/141 reads (42%) | called by muse, mutect2, varscan2
- FOXP2 | c.*3198C>T | 3'UTR (SNP) | VAF 8/207 reads (4%) | catalogued as rs1261779999; called by muse, mutect2
- GPR107 | chr9:130141815 G>A | 3'Flank (SNP) | VAF 30/245 reads (12%) | catalogued as rs1249749346; called by muse, mutect2, varscan2
- IFT74 | c.*1G>A | 3'UTR (SNP) | VAF 21/198 reads (11%) | catalogued as rs777791918; called by muse, mutect2, varscan2
- MACF1 | c.15832-8276A>T | Intron (SNP) | VAF 60/207 reads (29%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86034C>T | Intron (SNP) | VAF 180/290 reads (62%) | catalogued as rs747384089, COSV72277400, COSV72278078; called by muse, mutect2, varscan2
- NKAIN4 | c.54+39G>A | Intron (SNP) | VAF 99/442 reads (22%) | catalogued as rs1421070274; called by muse, mutect2, varscan2
- NXPE1 | c.834-900A>C | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- PIP5K1C | c.1920+962G>A | Intron (SNP) | VAF 115/346 reads (33%) | catalogued as rs1374031633; called by muse, mutect2, varscan2
- TPRX2P | n.820_821del | RNA (DEL) | VAF 57/291 reads (20%) | called by mutect2, pindel, varscan2
- UTS2B | c.*25del | 3'UTR (DEL) | VAF 15/74 reads (20%) | catalogued as rs771807888, COSV100484173; called by mutect2, pindel, varscan2
- ZNF420 | c.*1059dup | 3'UTR (INS) | VAF 53/242 reads (22%) | called by mutect2, varscan2
